CCDI case PBBUNY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d7788166-6b74-4234-8a3f-f687103c8090

Demographics
Sex at birth: male.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 8.3 years (3,036 days).

Biospecimens (3 samples)
- Sample 0DHZRU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHZRY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHZS4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
